TCGA case TCGA-AO-A0J5 — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c1442467-d618-435f-8792-b1a18f696f1a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 792 days (2.2 years).

Diagnoses (1)
1. Infiltrating duct mixed with other types of carcinoma: ICD-O-3 morphology code: 8523/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 48.8 years (17,815 days); Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC pathologic T: T4; AJCC pathologic N: N1a; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Sites of involvement: Lung, NOS / Bone, NOS / Liver / Breast, Right Upper Inner / Breast, Right Upper Outer / Breast, Right Lower Inner / Breast, Right Lower Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 2; Micrometastasis present: No.
   Treatment given: Treatment type: Bisphosphonate Therapy; Therapeutic agents: Zoledronic Acid; Treatment intent type: Neoadjuvant; Days to treatment start: -1 day; Treatment outcome: Treatment Ongoing; Prescribed dose: 4; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Treatment intent type: Neoadjuvant; Days to treatment start: 9 days; Days to treatment end: 422 days (1.2 years); Prescribed dose: 2.5; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 336 days; Days to treatment end: 371 days (1.0 years); Treatment dose: 10,625 cGy; Course number: 1; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Initial disease status: Progressive Disease; Days to treatment start: 422 days (1.2 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 1500; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Fulvestrant; Initial disease status: Progressive Disease; Days to treatment start: 618 days (1.7 years); Treatment outcome: Treatment Ongoing; Prescribed dose: 250; Prescribed dose units: mg; Route of administration: Intramuscular.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Indeterminate; Treatment anatomic sites: Breast.

Follow-up (3 entries)
- Days to follow up: 705 days (1.9 years); Disease response: With Tumor.
- Days to follow up: 735 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 792 days (2.2 years); Disease response: With Tumor.

Molecular and laboratory tests
- ERBB2 (FISH): 1.1; Cell count: 25; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 71; Cell count: 25.
- ERBB2 (IHC): Equivocal; Staining intensity value: 2+; Test value range: 10-19%.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity value: 4+; Test value range: 90-99%.
- PGR (IHC): Negative; Test value range: <10%.
- Test (FISH): Copy Number Reported; Copy number: 64; Cell count: 25.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A0J5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 500 mg.
  Slide TCGA-AO-A0J5-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 18; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A0J5-01A-01-BSA: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 1; Percent necrosis: 0; Percent stromal cells: 14; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A0J5-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A0J5-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: Yes; Tumor status: With tumor; Her2 cent17 ratio: 1.1; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Ductal/micropapillary; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Micromet detection by IHC: No; Er IHC score: 4+; Her2 IHC score: 2+; Margin status: Close; Method initial path diagnosis: Core needle biopsy; Her2 positivity method text: 3+ Positive; Her2 and cent17 scale other: >2.2 Positive; Prospective collection: No; Retrospective collection: Yes; Pr status IHC percent positive: <10%.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Inner Quadrant; Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right Lower Inner Quadrant; Anatomic organ subdivision: Right Lower Outer Quadrant; Anatomic organ subdivision: Right.
- First nonlymph node metastasis anatomic sites: Metastasis site: Lung; Metastasis site: Bone; Metastasis site: Liver.
- Follow-up form 2: Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Neo-adjuvant.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Pharmaceutical therapy drug name: Xeloda (Capecitabine); Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 1; Pharmaceutical therapy drug name: Femara (Letrozole); Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Neo-Adjuvant.
- Drug treatment 4: Regimen number: 3; Pharmaceutical therapy drug name: Fulvestrant (Faslodex); Therapy regimen: Progression.
- Drug treatment 4, Route of administrations: Route of administration: IM.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 792 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 792 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 792 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A0J5-01A-11D-A036-01): tumor purity 0.64, ploidy 1.97, whole-genome doublings 0.
